FM case AD6468 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Uterus, NOS.
https://portal.gdc.cancer.gov/cases/30d695d1-0932-4730-bfd6-df55aeff9b0f

Female, 66.4 years: Adenocarcinoma, NOS (ICD-O-3 8140/3) of the uterus; primary biopsied or resected from the uterus. Tumor nuclei on the sequenced sample's slide: 40% (pathologist estimate recorded by GDC). Sample type: Primary Tumor.
